Somatic mutation profile of tumor specimen MMRF_2608_1_BM_CD138pos (aliquot MMRF_2608_1_BM_CD138pos_T1_KHS5U_L12913) from MMRF case MMRF_2608, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.5 years (24,643 days).
Specimen MMRF_2608_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b344c0e-4a1f-48ea-b91a-8e4f8e110552.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2608_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2608_1_PB_Whole_C3_KHS5U_L12914; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bea33524-1523-4db3-bf4d-e901b5ee9378

The open-access MAF lists 336 somatic variants for this specimen: 121 protein-altering or splice-affecting, 43 silent, 172 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, 3'UTR 94, Silent 43, Intron 33, 5'UTR 17, 3'Flank 14, 5'Flank 7, RNA 7, Nonsense Mutation 3, Splice Region 3, Frame Shift Del 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.835); catalogued as rs756496192, CM156144, COSV56515660; called by muse, mutect2, varscan2
- AP3B2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1393295194, COSV55611161; called by muse, mutect2
- C1orf56 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs587635166; called by muse, mutect2, varscan2
- CCND3 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1006519914; called by muse, varscan2
- CDC16 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 5/113 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV52961529; called by muse, mutect2
- CDH10 | c.2177C>T p.T726I | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100050822, COSV52591531; called by muse, mutect2, varscan2
- CPN2 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 82/150 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60472527; called by muse, mutect2, varscan2
- DUSP2 | c.388G>C p.G130R | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1468530727, COSV56619784; called by muse, mutect2, varscan2
- EMILIN1 | c.1898G>A p.G633E | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV53158073; called by muse, mutect2
- ERI2 | c.2008A>T p.I670F | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs199629775; called by muse, mutect2
- GAD2 | c.78G>A p.A26= | Splice Region (SNP) | VAF 23/110 reads (21%) | catalogued as COSV52153247, COSV52172517; called by muse, mutect2, varscan2
- GALT | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.216); catalogued as rs766896883; called by muse, mutect2
- IDUA | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); catalogued as rs1029767148; called by muse, mutect2, varscan2
- IGHV1-69 | c.151T>A p.Y51N | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs781961965; called by mutect2, varscan2
- IGHV2-70 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs72690597; called by muse, varscan2
- IGLL5 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs762998471, COSV73248971, COSV73251039; called by muse, mutect2, varscan2
- IGLL5 | c.415A>G p.S139G | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.211); catalogued as rs1311182123; called by muse, mutect2, varscan2
- IGLV3-1 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 103/108 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs774205851; called by muse, mutect2, varscan2
- IGLV3-1 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 92/100 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs373605544; called by muse, varscan2
- IGLV3-25 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 142/284 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as rs779833481; called by muse, mutect2, varscan2
- JAKMIP1 | c.2239G>A p.G747S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs774733621, COSV68954159; called by muse, mutect2, varscan2
- KCNA5 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239077980, COSV52908237; called by muse, mutect2, varscan2
- KIF1C | c.3266G>A p.R1089Q | Missense Mutation (SNP) | VAF 103/202 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs535655372; called by muse, mutect2, varscan2
- KLHL29 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 125/305 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1392833200, COSV72085945; called by muse, mutect2, varscan2
- KRTAP29-1 | c.242T>G p.V81G | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV66939849; called by muse, mutect2
- MAPK15 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 90/145 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202182231; called by muse, mutect2, varscan2
- MCUR1 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs936480258; called by muse, mutect2, varscan2
- NTN1 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758553071, COSV99432498, COSV99433885; called by muse, mutect2, varscan2
- NUDT7 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 96/133 reads (72%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs370570737; called by muse, mutect2, varscan2
- OR8J3 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV100040712; called by muse, mutect2
- P3H2 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 55/89 reads (62%) | catalogued as COSV60018586; called by muse, mutect2, varscan2
- PIWIL3 | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780894038, COSV100177889; called by muse, mutect2, varscan2
- PLCZ1 | c.1589A>G p.N530S | Missense Mutation (SNP) | VAF 59/344 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs982833347; called by muse, mutect2, varscan2
- PRDM16 | c.3187G>A p.A1063T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766687660, COSV54592446; called by muse, mutect2, varscan2
- RET | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.143); catalogued as rs1427186016, COSV60710609; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SBSPON | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs1438183790; called by muse, mutect2, varscan2
- SDK1 | c.4228G>A p.G1410R | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1487618798, COSV67385135; called by muse, mutect2, varscan2
- SH3GLB2 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV65330580; called by muse, mutect2, varscan2
- SHPRH | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs371743858; called by muse, mutect2, varscan2
- SRRM4 | c.1674C>A p.S558R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as rs750188540, COSV57416298; called by muse, mutect2, varscan2
- TAPT1 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1335552338; called by muse, mutect2, varscan2
- TBX3 | c.1970C>T p.T657I (on ENST00000257566 / NM_016569.4; = p.T637I on NM_005996.4) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV57473729, COSV57474358; called by muse, mutect2, varscan2
- TDRD15 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs573334128; called by muse, mutect2, varscan2
- TMEM250 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as rs763001457, COSV69307356; called by muse, mutect2, varscan2
- TREX2 | c.326C>T p.P109L (on ENST00000334497; = p.P66L on NM_080701.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs144682302, COSV57851487; called by muse, mutect2, varscan2
- TTC6 | c.392C>T p.A131V (on ENST00000267368; = p.A1497V on NM_001310135.3) | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.244); catalogued as rs1416798847; called by muse, mutect2, varscan2
- UGT2B7 | c.593T>C p.M198T | Missense Mutation (SNP) | VAF 101/142 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs777273975; called by muse, mutect2, varscan2
- ZIC1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 77/141 reads (55%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.043); catalogued as COSV51553274; called by muse, mutect2, varscan2
- ZNF536 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV62834762; called by muse, mutect2, varscan2
- ZSCAN5A | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs141778812; called by muse, mutect2, varscan2
- ADCY8 | c.3268G>T p.G1090C | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRA3 | c.3094G>T p.G1032* | Nonsense Mutation (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- AHNAK2 | c.14695G>A p.G4899R | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP11C | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.42); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C19orf81 | c.139T>C p.S47P | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- C9orf116 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 108/232 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CNTN1 | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- COL14A1 | c.1885T>G p.Y629D | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CREB3L2 | c.583+2_583+6dup | Splice Region (INS) | VAF 115/248 reads (46%) | called by mutect2, pindel, varscan2
- CUBN | c.3016G>A p.G1006R | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHRS4 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DLG5 | c.2912A>C p.K971T | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMD | c.3839A>C p.K1280T | Missense Mutation (SNP) | VAF 33/35 reads (94%) | SIFT tolerated (0.52); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- DTX1 | c.217A>C p.I73L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DUSP4 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EGR2 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ENGASE | c.1862_1864dup p.A621dup | In Frame Ins (INS) | VAF 31/77 reads (40%) | called by mutect2, pindel, varscan2
- FAM124B | c.695A>G p.Q232R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- FMNL3 | c.45del p.S16Lfs*27 | Frame Shift Del (DEL) | VAF 72/230 reads (31%) | called by mutect2, pindel, varscan2
- FNDC3A | c.1466A>C p.K489T (on ENST00000492622 / NM_001079673.2; = p.K433T on NM_014923.5) | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- FREM1 | c.1507C>A p.H503N | Missense Mutation (SNP) | VAF 85/183 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GANC | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 191/421 reads (45%) | PolyPhen benign (0.145); called by muse, mutect2, varscan2
- GDI2 | c.997T>A p.Y333N | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM5 | c.2447G>T p.C816F | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HORMAD2 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IGHD | c.278G>C p.S93T | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV3-16 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.898); called by muse, varscan2
- KLHDC2 | c.530T>C p.F177S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- KLHL6 | c.293+2T>G p.X98_splice | Splice Site (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- KRT40 | c.914T>G p.I305S | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2
- LRP1B | c.10520A>C p.E3507A | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRTM3 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- METTL25 | c.1049_1053del p.S350* | Frame Shift Del (DEL) | VAF 38/79 reads (48%) | called by mutect2, pindel, varscan2
- MICALL1 | c.937A>C p.T313P | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MRO | c.-126-5G>C | Splice Region (SNP) | VAF 108/186 reads (58%) | called by muse, mutect2, varscan2
- MTMR8 | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH8 | c.1575G>T p.E525D | Missense Mutation (SNP) | VAF 14/500 reads (3%) | SIFT tolerated (0.83); PolyPhen benign (0.006); called by muse, mutect2
- MYL6B | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- NCOA2 | c.2510_2513del p.Q837Pfs*76 | Frame Shift Del (DEL) | VAF 26/56 reads (46%) | called by pindel, varscan2
- NPAP1 | c.491A>C p.E164A | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- NUP153 | c.3137G>A p.S1046N | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NWD2 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PANK4 | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PARD3B | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB15 | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 69/293 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIKFYVE | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PIPOX | c.1102T>A p.L368I | Missense Mutation (SNP) | VAF 182/366 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PLOD2 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PMEL | c.1578G>A p.M526I | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PTPRD | c.4901A>C p.Q1634P | Missense Mutation (SNP) | VAF 98/206 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- RCN2 | c.160_168del p.Y54_K56del | In Frame Del (DEL) | VAF 12/150 reads (8%) | called by mutect2, pindel
- RHOU | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 79/274 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SCG2 | c.359A>C p.Q120P | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- SEMA3E | c.1030T>G p.Y344D | Missense Mutation (SNP) | VAF 95/170 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3TC2 | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- SMARCD3 | c.599A>C p.K200T (on ENST00000262188 / NM_001003801.2; = p.K187T on NM_003078.4) | Missense Mutation (SNP) | VAF 76/134 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SMURF1 | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPI1 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 17/533 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- SRSF8 | c.845C>G p.S282C | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); called by muse, mutect2
- SYDE2 | c.2760T>A p.S920R | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.006); called by muse, mutect2
- TCIRG1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TEKT3 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TLR5 | c.1535A>C p.N512T | Missense Mutation (SNP) | VAF 300/451 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TNRC6A | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TTC14 | c.1928G>C p.G643A | Missense Mutation (SNP) | VAF 64/464 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- USH2A | c.7165A>T p.S2389C | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- WWC1 | c.1775A>G p.E592G | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZFHX4 | c.6978C>A p.D2326E | Missense Mutation (SNP) | VAF 48/345 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF433 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZNF503 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF880 | c.640T>G p.C214G | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AMHR2 | c.1104C>A p.T368= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as rs757659134; called by muse, mutect2, varscan2
- AP002512.3 | c.1149A>T p.T383= | Silent (SNP) | VAF 105/185 reads (57%) | called by muse, mutect2, varscan2
- BRPF3 | c.54G>A p.P18= | Silent (SNP) | VAF 87/173 reads (50%) | catalogued as rs562183508, COSV100325782; called by muse, mutect2, varscan2
- C9orf116 | c.405C>T p.C135= | Silent (SNP) | VAF 108/226 reads (48%) | catalogued as rs778322949; called by mutect2, varscan2
- CACNA1H | c.852C>T p.G284= | Silent (SNP) | VAF 181/347 reads (52%) | catalogued as rs1567507548; called by muse, mutect2, varscan2
- CCND3 | c.193C>T p.L65= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, varscan2
- CCND3 | c.18C>T p.C6= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV65912592; called by muse, mutect2
- CHD7 | c.6393T>C p.F2131= | Silent (SNP) | VAF 70/178 reads (39%) | called by muse, mutect2, varscan2
- COL6A3 | c.7149C>T p.I2383= | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- DYRK4 | c.76T>C p.L26= | Silent (SNP) | VAF 79/206 reads (38%) | called by muse, mutect2, varscan2
- EDEM1 | c.426C>T p.Y142= | Silent (SNP) | VAF 140/400 reads (35%) | catalogued as rs750350351; called by muse, varscan2
- GABBR1 | c.2067C>T p.H689= | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as rs755512702; called by muse, mutect2, varscan2
- GALR1 | c.288C>T p.Y96= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as COSV55317496; called by muse, mutect2, varscan2
- GDF10 | c.594C>T p.R198= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1555207489; called by muse, mutect2, varscan2
- GGCX | c.1263C>T p.G421= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs373716493, COSV52087954; called by muse, mutect2, varscan2
- GRTP1 | c.666C>T p.L222= | Silent (SNP) | VAF 62/163 reads (38%) | catalogued as rs752540541, COSV100208644; called by muse, mutect2, varscan2
- HECTD4 | c.1773G>A p.L591= | Silent (SNP) | VAF 82/193 reads (42%) | called by muse, mutect2, varscan2
- HHIPL1 | c.1254C>T p.G418= | Silent (SNP) | VAF 58/96 reads (60%) | called by muse, mutect2, varscan2
- IGHA1 | c.726G>C p.L242= | Silent (SNP) | VAF 43/65 reads (66%) | catalogued as rs763594966; called by muse, mutect2, varscan2
- IGHA2 | c.66G>A p.V22= | Silent (SNP) | VAF 70/242 reads (29%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.282C>T p.S94= | Silent (SNP) | VAF 188/202 reads (93%) | catalogued as rs782505792; called by muse, varscan2
- IGHV2-70D | c.138C>T p.F46= | Silent (SNP) | VAF 55/62 reads (89%) | called by muse, varscan2
- IGLL5 | c.162C>T p.A54= | Silent (SNP) | VAF 17/18 reads (94%) | catalogued as rs767463354, COSV73250848; called by muse, mutect2, varscan2
- KDM5D | c.3873G>T p.L1291= | Silent (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- LAMA3 | c.9405A>C p.S3135= (on ENST00000313654 / NM_198129.4; = p.S1526= on NM_000227.6) | Silent (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- MAPK7 | c.2313C>T p.A771= | Silent (SNP) | VAF 28/267 reads (10%) | called by muse, mutect2, varscan2
- MED12L | c.5253C>T p.S1751= | Silent (SNP) | VAF 68/118 reads (58%) | catalogued as rs762751794, COSV56395091; called by muse, mutect2, varscan2
- MUC12 | c.15714C>A p.I5238= (on ENST00000379442; = p.I5095= on NM_001164462.1) | Silent (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- NEURL4 | c.1935C>T p.D645= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs765388042; called by muse, varscan2
- NIBAN1 | c.1177C>T p.L393= | Silent (SNP) | VAF 44/257 reads (17%) | catalogued as COSV62284275; called by muse, mutect2, varscan2
- NUP205 | c.774T>C p.V258= | Silent (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- OR4S2 | c.921G>A p.E307= | Silent (SNP) | VAF 123/126 reads (98%) | catalogued as rs1469555006; called by muse, mutect2, varscan2
- OR6N1 | c.360C>T p.Y120= | Silent (SNP) | VAF 32/207 reads (15%) | catalogued as rs374981578; called by muse, mutect2, varscan2
- PABPC1 | c.6C>T p.N2= | Silent (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- PDCD11 | c.1893A>G p.K631= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs144933488; called by muse, mutect2, varscan2
- PEAR1 | c.2730G>A p.E910= | Silent (SNP) | VAF 143/436 reads (33%) | catalogued as COSV99441806; called by muse, mutect2, varscan2
- PHF21B | c.270G>C p.R90= | Silent (SNP) | VAF 79/170 reads (46%) | called by muse, mutect2, varscan2
- PTK6 | c.813C>T p.S271= | Silent (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- SGSM1 | c.2001C>T p.I667= | Silent (SNP) | VAF 56/103 reads (54%) | catalogued as rs766453029, COSV68512671; called by muse, mutect2, varscan2
- SLCO4A1 | c.636C>T p.P212= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs191944548; called by muse, mutect2, varscan2
- SYNJ1 | c.771C>T p.V257= | Silent (SNP) | VAF 43/353 reads (12%) | called by muse, mutect2, varscan2
- WNK2 | c.2874G>A p.P958= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs373635754; called by muse, mutect2, varscan2
- XKR4 | c.168G>A p.P56= | Silent (SNP) | VAF 31/45 reads (69%) | catalogued as COSV59301068; called by muse, mutect2, varscan2
- AADACL4 | c.*171A>G | 3'UTR (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- AC005863.1 | n.2928T>G | RNA (SNP) | VAF 36/73 reads (49%) | catalogued as rs1159163741; called by muse, mutect2, varscan2
- AC011525.1 | n.842C>T | RNA (SNP) | VAF 16/234 reads (7%) | catalogued as rs1281027754; called by muse, mutect2
- AC090616.1 | n.384C>A | RNA (SNP) | VAF 11/212 reads (5%) | called by muse, mutect2
- ADGRG5 | c.*1103G>C | 3'UTR (SNP) | VAF 65/85 reads (76%) | called by muse, mutect2, varscan2
- ADORA1 | c.*30T>C | 3'UTR (SNP) | VAF 22/323 reads (7%) | called by muse, mutect2
- AJUBA | c.*1850T>C | 3'UTR (SNP) | VAF 61/115 reads (53%) | called by muse, mutect2, varscan2
- AK4 | c.*3335C>T | 3'UTR (SNP) | VAF 11/14 reads (79%) | catalogued as rs899116850; called by muse, mutect2, varscan2
- ANKRD20A11P | n.46G>A | RNA (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499288 T>C | 5'Flank (SNP) | VAF 48/91 reads (53%) | catalogued as rs757888993; called by muse, mutect2, varscan2
- APBB3 | c.-183G>A | 5'UTR (SNP) | VAF 69/114 reads (61%) | called by muse, mutect2, varscan2
- ARL13A | c.*30T>A | 3'UTR (SNP) | VAF 19/25 reads (76%) | called by muse, mutect2, varscan2
- BCL2 | c.*1510T>C | 3'UTR (SNP) | VAF 49/86 reads (57%) | catalogued as rs1442859273; called by muse, mutect2, varscan2
- BHLHE22 | c.*770T>C | 3'UTR (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- BIRC3 | c.-1356G>A | 5'UTR (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- BTBD1 | c.1056-25T>C | Intron (SNP) | VAF 33/66 reads (50%) | catalogued as rs1278163334; called by muse, mutect2, varscan2
- C15orf40 | c.*325C>A | 3'UTR (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- C1QTNF6 | c.*1075T>G | 3'UTR (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- C1orf21 | c.*4865G>C | 3'UTR (SNP) | VAF 67/256 reads (26%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81947275 T>G | 3'Flank (SNP) | VAF 53/100 reads (53%) | called by muse, mutect2, varscan2
- CALCR | c.*709G>C | 3'UTR (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- CAMKMT | c.376+66330T>C | Intron (SNP) | VAF 16/274 reads (6%) | called by muse, mutect2
- CAP2 | c.*270C>A | 3'UTR (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- CAPZA3 | c.-34C>A | 5'UTR (SNP) | VAF 38/293 reads (13%) | called by muse, mutect2, varscan2
- CCDC144B | n.107G>C | RNA (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- CCDC15 | c.*671A>T | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- CCND3 | c.*698T>G | 3'UTR (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- CCND3 | c.199-55C>A | Intron (SNP) | VAF 65/138 reads (47%) | called by muse, varscan2
- CCND3 | c.199-101C>T | Intron (SNP) | VAF 62/146 reads (42%) | called by muse, varscan2
- CCND3 | c.198+287A>T | Intron (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- CDH12 | c.*549G>T | 3'UTR (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- CDH8 | c.*115T>C | 3'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- CDR1 | chrX:140783316 G>A | 3'Flank (SNP) | VAF 62/62 reads (100%) | catalogued as rs763115319; called by muse, mutect2, varscan2
- CEP295 | chr11:93734626 T>G | 3'Flank (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2
- CFAP251 | c.*150A>G | 3'UTR (SNP) | VAF 15/46 reads (33%) | catalogued as rs953594695; called by muse, varscan2
- CLCN3 | c.161-19871A>T | Intron (SNP) | VAF 28/36 reads (78%) | called by muse, mutect2, varscan2
- CMSS1 | c.*12A>C | 3'UTR (SNP) | VAF 130/317 reads (41%) | called by muse, mutect2, varscan2
- CNTN5 | c.2730+419T>G | Intron (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- CNTRL | c.3964-264A>G | Intron (SNP) | VAF 80/156 reads (51%) | called by muse, mutect2, varscan2
- CSNK1A1L | c.-362G>A | 5'UTR (SNP) | VAF 71/155 reads (46%) | catalogued as rs1319364582; called by muse, mutect2, varscan2
- CXCL6 | c.*259A>T | 3'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- CYLC2 | c.-30T>G | 5'UTR (SNP) | VAF 150/343 reads (44%) | catalogued as COSV66336900; called by muse, mutect2, varscan2
- DAGLA | c.*1513G>T | 3'UTR (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- DCDC2 | c.*1163G>T | 3'UTR (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- DLG2 | c.*1348G>T | 3'UTR (SNP) | VAF 73/146 reads (50%) | catalogued as rs535837353; called by muse, mutect2, varscan2
- DLGAP2 | c.*3857C>T | 3'UTR (SNP) | VAF 17/177 reads (10%) | called by muse, mutect2, varscan2
- DNM1 | c.*120T>A | 3'UTR (SNP) | VAF 18/316 reads (6%) | called by muse, mutect2
- DPYSL3 | c.*2860G>A | 3'UTR (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- DTX1 | c.-10A>G | 5'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, varscan2
- DUSP15 | c.*572C>T | 3'UTR (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2, varscan2
- DUSP26 | c.*413G>A | 3'UTR (SNP) | VAF 32/211 reads (15%) | called by muse, mutect2, varscan2
- EEA1 | c.*1952_*1953insCT | 3'UTR (INS) | VAF 28/50 reads (56%) | catalogued as rs1298190938; called by mutect2, varscan2
- ELAVL4 | chr1:50203577 del A | 3'Flank (DEL) | VAF 40/105 reads (38%) | catalogued as rs995627898; called by mutect2, varscan2
- EMX1 | chr2:72916680 T>G | 5'Flank (SNP) | VAF 23/172 reads (13%) | called by muse, mutect2, varscan2
- ENPP6 | c.*1598C>T | 3'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2
- F13A1 | c.*754C>T | 3'UTR (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- FAM167A | c.*2891A>C | 3'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2
- FAM98B | chr15:38484571 A>G | 3'Flank (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- FHL2 | chr2:105359978 A>G | 3'Flank (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- FOXD3 | c.-8G>A | 5'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+5431G>A | Intron (SNP) | VAF 18/59 reads (31%) | catalogued as rs1005153845; called by muse, mutect2, varscan2
- GABRG1 | c.*3887G>T | 3'UTR (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- GASK1B | c.-216C>T | 5'UTR (SNP) | VAF 11/49 reads (22%) | catalogued as rs1271825616; called by muse, mutect2, varscan2
- GPR26 | c.*1627T>C | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- GSE1 | c.*2568A>C | 3'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- H4C5 | c.*268G>C | 3'UTR (SNP) | VAF 46/92 reads (50%) | catalogued as rs1221416824, COSV63486478; called by muse, mutect2, varscan2
- HCAR1 | c.*295A>G | 3'UTR (SNP) | VAF 64/210 reads (30%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.*540A>C | 3'UTR (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- HIF1A | c.-163T>G | 5'UTR (SNP) | VAF 76/209 reads (36%) | called by muse, mutect2, varscan2
- IFT43 | chr14:76083745 T>G | 3'Flank (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- IGLL5 | c.*108dup | 3'UTR (INS) | VAF 91/927 reads (10%) | called by mutect2, pindel
- IKBIP | c.297+9092T>C | Intron (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- IL6R | c.-26C>T | 5'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- INPP4B | chr4:142024588 T>C | 3'Flank (SNP) | VAF 51/71 reads (72%) | called by muse, mutect2, varscan2
- INSM2 | c.*749T>G | 3'UTR (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- ITGA2 | c.*886G>A | 3'UTR (SNP) | VAF 85/259 reads (33%) | called by muse, mutect2, varscan2
- KDR | c.*23C>G | 3'UTR (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99818315; called by muse, mutect2, varscan2
- KIAA1217 | c.5334+312G>A | Intron (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- KIF5C | c.-315C>T | 5'UTR (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- KMT2A | c.432+667A>C | Intron (SNP) | VAF 44/148 reads (30%) | catalogued as rs529709559; called by muse, mutect2, varscan2
- LILRB5 | c.1256-151C>T | Intron (SNP) | VAF 148/267 reads (55%) | called by muse, mutect2, varscan2
- LIMCH1 | c.*1822A>T | 3'UTR (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- LINC01098 | n.876G>A | RNA (SNP) | VAF 73/267 reads (27%) | catalogued as rs1411280116; called by muse, mutect2, varscan2
- LRRC28 | c.168+2483_168+2486del | Intron (DEL) | VAF 8/62 reads (13%) | called by pindel, varscan2
- LRRC8B | c.*4223_*4224del | 3'UTR (DEL) | VAF 40/78 reads (51%) | called by mutect2, pindel, varscan2
- LSM14B | c.*251C>G | 3'UTR (SNP) | VAF 208/428 reads (49%) | called by muse, mutect2, varscan2
- LTB | c.208+45G>C | Intron (SNP) | VAF 101/245 reads (41%) | called by muse, mutect2, varscan2
- LTB | c.163-96A>G | Intron (SNP) | VAF 238/438 reads (54%) | catalogued as rs541371875; called by muse, varscan2
- LTB | c.163-101G>A | Intron (SNP) | VAF 180/420 reads (43%) | catalogued as rs542279471; called by muse, varscan2
- MAEA | c.*120C>T | 3'UTR (SNP) | VAF 30/41 reads (73%) | called by muse, mutect2, varscan2
- MAP11 | c.*229dup | 3'UTR (INS) | VAF 43/70 reads (61%) | catalogued as rs1355654101; called by mutect2, varscan2
- MAU2 | c.1309-225C>T | Intron (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- MCM9 | c.*1185T>G | 3'UTR (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851124 A>C | 5'Flank (SNP) | VAF 198/293 reads (68%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851243 T>G | 5'Flank (SNP) | VAF 67/231 reads (29%) | catalogued as rs763721827; called by muse, varscan2
- MIR5195 | chr14:106851324 C>A | 5'Flank (SNP) | VAF 61/190 reads (32%) | catalogued as rs572738324; called by muse, varscan2
- MOB1A | c.*846C>G | 3'UTR (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- MOB1B | c.*5584C>T | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- MPP6 | c.*1828C>T | 3'UTR (SNP) | VAF 20/46 reads (43%) | catalogued as rs78831923; called by muse, mutect2
- MR1 | c.*3332G>T | 3'UTR (SNP) | VAF 34/150 reads (23%) | called by muse, mutect2, varscan2
- MRPL10 | c.*208C>T | 3'UTR (SNP) | VAF 11/231 reads (5%) | called by muse, mutect2
- MTMR9 | c.*673G>A | 3'UTR (SNP) | VAF 52/106 reads (49%) | catalogued as rs190273266; called by muse, mutect2, varscan2
- MUC5B | c.3455-128G>A | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- MYLIP | c.*906T>C | 3'UTR (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- NECAP2 | c.*122_*124del | 3'UTR (DEL) | VAF 51/124 reads (41%) | catalogued as rs762562655; called by mutect2, pindel, varscan2
- NFIB | c.*2864T>A | 3'UTR (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- NFIB | c.*42C>A | 3'UTR (SNP) | VAF 172/378 reads (46%) | called by muse, mutect2, varscan2
- PAEP | c.*191G>C | 3'UTR (SNP) | VAF 23/211 reads (11%) | called by muse, mutect2, varscan2
- PCDH7 | c.*1129A>C | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- PCDHAC1 | c.*1592G>A | 3'UTR (SNP) | VAF 34/50 reads (68%) | called by muse, mutect2, varscan2
- PCK1 | c.407-63del | Intron (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- PHKA1 | c.*846C>A | 3'UTR (SNP) | VAF 68/68 reads (100%) | called by muse, mutect2, varscan2
- PKHD1 | c.*1873C>T | 3'UTR (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- PLCXD3 | c.*709dup | 3'UTR (INS) | VAF 93/249 reads (37%) | called by mutect2, pindel, varscan2
- PPARGC1A | c.877+3718A>C | Intron (SNP) | VAF 30/34 reads (88%) | called by muse, mutect2, varscan2
- PPATP1 | n.1479T>A | RNA (SNP) | VAF 48/338 reads (14%) | called by muse, mutect2, varscan2
- PPP4R3B | c.-56G>C | 5'UTR (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- PPRC1 | chr10:102133017 T>C | 5'Flank (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- PRDM5 | c.300+15465A>T | Intron (SNP) | VAF 55/81 reads (68%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*2475G>A | 3'UTR (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- PRLR | c.*8469C>T | 3'UTR (SNP) | VAF 42/83 reads (51%) | catalogued as rs1426065155; called by muse, mutect2, varscan2
- PROKR2 | c.-48C>A | 5'UTR (SNP) | VAF 31/209 reads (15%) | catalogued as rs1405907324; called by muse, mutect2, varscan2
- PRPF38A | c.-3A>T | 5'UTR (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- PRPF4B | c.*1259C>T | 3'UTR (SNP) | VAF 4/58 reads (7%) | catalogued as rs981353323; called by muse, mutect2
- PRRT4 | c.*197G>T | 3'UTR (SNP) | VAF 58/102 reads (57%) | called by muse, mutect2, varscan2
- RC3H1 | c.*2155dup | 3'UTR (INS) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- RGS21 | c.*902A>G | 3'UTR (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- RHBDD1 | c.*1640C>A | 3'UTR (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- RIMS3 | chr1:40626056 G>C | 3'Flank (SNP) | VAF 17/103 reads (17%) | catalogued as COSV65505326; called by muse, mutect2, varscan2
- RNF182 | c.*1266C>G | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- ROPN1 | c.116+67C>T | Intron (SNP) | VAF 211/671 reads (31%) | catalogued as rs1185768797; called by muse, mutect2, varscan2
- RSPO2 | c.95-7850G>A | Intron (SNP) | VAF 187/314 reads (60%) | called by muse, mutect2, varscan2
- S1PR3 | c.-148+1645dup | Intron (INS) | VAF 14/63 reads (22%) | called by mutect2, varscan2
- SATB2 | c.*2481A>T | 3'UTR (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- SCAF4 | c.-242C>T | 5'UTR (SNP) | VAF 44/115 reads (38%) | called by muse, mutect2, varscan2
- SCLT1 | c.235-621G>A | Intron (SNP) | VAF 44/66 reads (67%) | called by muse, mutect2, varscan2
- SCN1A | c.*1455dup | 3'UTR (INS) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- SEMA3C | c.*219T>G | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- SEMA3E | c.*1808T>C | 3'UTR (SNP) | VAF 35/88 reads (40%) | called by muse, mutect2, varscan2
- SETBP1 | c.*2865G>A | 3'UTR (SNP) | VAF 21/141 reads (15%) | called by muse, mutect2, varscan2
- SGTB | c.*3555T>C | 3'UTR (SNP) | VAF 86/154 reads (56%) | called by muse, mutect2, varscan2
- SLAIN1 | c.701-2694T>G | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- SLAMF8 | c.*758G>A | 3'UTR (SNP) | VAF 31/227 reads (14%) | called by muse, mutect2, varscan2
- SMARCA5 | c.*2968T>A | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- SMG7 | c.*1054G>A | 3'UTR (SNP) | VAF 159/233 reads (68%) | catalogued as rs1325850375; called by muse, mutect2, varscan2
- SNX13 | c.2627-473A>T | Intron (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- SNX18 | c.1774+886G>C | Intron (SNP) | VAF 62/145 reads (43%) | called by muse, mutect2, varscan2
- SOHLH2 | c.*741G>T | 3'UTR (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15968062 G>T | 3'Flank (SNP) | VAF 65/103 reads (63%) | called by muse, mutect2, varscan2
- SPRED2 | c.*2624G>A | 3'UTR (SNP) | VAF 23/48 reads (48%) | catalogued as rs748111135; called by muse, mutect2, varscan2
- SRF | c.*1828G>T | 3'UTR (SNP) | VAF 16/165 reads (10%) | called by muse, mutect2
- SSH1 | c.*2837A>G | 3'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- STOX2 | c.-983G>A | 5'UTR (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- SV2C | c.*11dup | 3'UTR (INS) | VAF 40/70 reads (57%) | catalogued as rs779155256; called by mutect2, varscan2
- SYMPK | c.2491-26C>T | Intron (SNP) | VAF 32/60 reads (53%) | catalogued as rs761258527; called by muse, mutect2, varscan2
- SYNE2 | chr14:64227816 T>C | 3'Flank (SNP) | VAF 34/408 reads (8%) | catalogued as rs1399788088; called by muse, mutect2
- TCEAL9 | chrX:103358413 A>G | 3'Flank (SNP) | VAF 58/59 reads (98%) | called by muse, mutect2, varscan2
- TMEM177 | chr2:119686080 G>A | 3'Flank (SNP) | VAF 49/102 reads (48%) | called by muse, mutect2, varscan2
- TMEM191B | chr22:18533988 C>T | 3'Flank (SNP) | VAF 13/30 reads (43%) | catalogued as rs1055501823; called by muse, mutect2, varscan2
- TNFRSF11B | c.*794T>G | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- TNRC6A | c.*307T>C | 3'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as rs1307776778; called by muse, varscan2
- TNRC6A | c.*361T>C | 3'UTR (SNP) | VAF 33/62 reads (53%) | called by muse, varscan2
- TP53 | c.*881C>G | 3'UTR (SNP) | VAF 16/17 reads (94%) | called by muse, mutect2, varscan2
- TSHR | c.*1762C>G | 3'UTR (SNP) | VAF 39/101 reads (39%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331245 T>C | 5'Flank (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- UHMK1 | c.*5392G>T | 3'UTR (SNP) | VAF 190/261 reads (73%) | catalogued as COSV99966423; called by muse, mutect2, varscan2
- UROS | c.394+30G>T | Intron (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- USP7 | c.2310-77A>T | Intron (SNP) | VAF 37/68 reads (54%) | catalogued as rs1400017181; called by muse, mutect2, varscan2
- VSTM2A | c.-300C>T | 5'UTR (SNP) | VAF 21/72 reads (29%) | catalogued as rs963285017; called by muse, mutect2, varscan2
- ZFHX4 | c.*928A>C | 3'UTR (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2
- ZKSCAN1 | c.*842C>T | 3'UTR (SNP) | VAF 94/197 reads (48%) | called by muse, mutect2, varscan2
- ZZEF1 | c.7405-128A>G | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
